Somatic mutation profile of tumor specimen TCGA-B5-A1MV-01A (aliquot TCGA-B5-A1MV-01A-31D-A14G-09) from TCGA case TCGA-B5-A1MV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 84.7 years (30,926 days).
Specimen TCGA-B5-A1MV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11706149-7216-45a2-a0bf-4040edb8b48e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A1MV-10A (Blood Derived Normal), aliquot TCGA-B5-A1MV-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3ce1623-9d0f-4f5e-9596-1637726b1e6b

The open-access MAF lists 76 somatic variants for this specimen: 55 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 20, Nonsense Mutation 4, Splice Site 3, Frame Shift Del 2, In Frame Del 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2303_2311dup p.S768_D770dup | In Frame Ins (INS) | VAF 14/37 reads (38%) | hotspot (GDC flag); catalogued as rs397517109; ClinVar: likely pathogenic / drug response; called by mutect2, varscan2
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1126G>A p.G376R (on ENST00000521381 / NM_181523.3; = p.G106R on NM_181504.4) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519757, COSV57123316, COSV57132021, COSV57133701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTL8 | c.958G>T p.V320F | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100958683; called by muse, mutect2, varscan2
- ACTR1A | c.455G>A p.R152K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as COSV100883721, COSV64023284; called by muse, mutect2, varscan2
- ALPK3 | c.3292G>A p.E1098K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV99361166; called by muse, mutect2, varscan2
- ALX4 | c.50T>C p.M17T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV100241120; called by muse, mutect2, varscan2
- ARID1A | c.3254C>G p.S1085* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV100249938, COSV61383854; called by muse, mutect2, varscan2
- DACT1 | c.1735G>A p.V579M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs1322099910, COSV60022638; called by muse, mutect2, varscan2
- DGAT1 | c.1378T>C p.S460P | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100184063; called by muse, mutect2, varscan2
- DSP | c.6565C>T p.R2189W | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs767661570, COSV65795354; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DST | c.8371C>A p.P2791T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.007); catalogued as COSV99757320; called by muse, mutect2, varscan2
- EMILIN2 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs755497750, COSV54426439; called by muse, mutect2, varscan2
- FBLN2 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.985); catalogued as rs773688519, COSV99852073; called by muse, mutect2, varscan2
- GPR141 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.302); catalogued as rs566037940, COSV57733549; called by muse, varscan2
- GPR34 | c.1034G>T p.R345L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.336); catalogued as COSV100587337, COSV59361292; called by mutect2, varscan2
- GRHL1 | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100257912; called by muse, mutect2, varscan2
- GTPBP4 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as rs201468419, COSV62550703; called by muse, mutect2, varscan2
- HSPA12A | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100979842; called by muse, mutect2, varscan2
- IDUA | c.1189+1G>A p.X397_splice | Splice Site (SNP) | VAF 3/11 reads (27%) | catalogued as COSV99926082; called by muse, mutect2
- IL36G | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs764738286, COSV52078637, COSV52079285; called by muse, mutect2, varscan2
- INPP4A | c.2308G>A p.V770M (on ENST00000074304 / NM_001134224.1; = p.V731M on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50853021; called by muse, mutect2, varscan2
- KNDC1 | c.4295G>A p.R1432H | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); catalogued as rs202204298; called by muse, mutect2, varscan2
- LRRK2 | c.1318G>T p.G440* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV54157855, COSV54162951; called by muse, mutect2
- MAB21L1 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100081295, COSV59823162; called by muse, mutect2, varscan2
- MAN2B1 | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99667054; called by mutect2, varscan2
- MAN2C1 | c.1627G>A p.V543M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs746348218, COSV99145472; called by muse, mutect2, varscan2
- MAP3K10 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV99454493; called by muse, mutect2
- MAP4 | c.2814G>T p.K938N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99275591; called by muse, mutect2, varscan2
- MED12 | c.4564G>A p.D1522N | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100378411; called by muse, mutect2, varscan2
- MORC4 | c.176-1G>T p.X59_splice | Splice Site (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99717301; called by muse, mutect2, varscan2
- MYH2 | c.5708G>A p.R1903H | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770302436, COSV55432703; called by muse, mutect2, varscan2
- NID2 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99356705; called by muse, mutect2
- OR5L2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs200162111, COSV65723663; called by muse, mutect2, varscan2
- OR6N2 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.091); catalogued as COSV100210223; called by muse, mutect2, varscan2
- OR8D2 | c.216C>A p.C72* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100659015; called by mutect2, varscan2
- OTUD6A | c.603C>A p.D201E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV100611015, COSV57972866; called by muse, mutect2, varscan2
- PCDHGA6 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as rs781113576, COSV99539028; called by muse, mutect2, varscan2
- PLCXD3 | c.426G>T p.L142F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100125863; called by mutect2, varscan2
- SLC2A14 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.158); catalogued as rs1271137485, COSV100533852; called by muse, mutect2, varscan2
- SLC4A9 | c.1438C>T p.R480C (on ENST00000507527 / NM_001258428.2; = p.R456C on NM_031467.3) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774917090, COSV50187232; called by muse, mutect2, varscan2
- SLC5A12 | c.1367C>G p.A456G | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV101237714, COSV68450447; called by muse, mutect2, varscan2
- ST18 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs750211258, COSV52499950, COSV99389969; called by muse, mutect2, varscan2
- SUGP1 | c.1010A>G p.K337R | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99895173; called by muse, mutect2, varscan2
- TENM1 | c.6721G>C p.A2241P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100950279, COSV100950775; called by muse, mutect2, varscan2
- TEX11 | c.450+1G>C p.X150_splice (on ENST00000344304; = p.X135_splice on NM_031276.3) | Splice Site (SNP) | VAF 11/55 reads (20%) | catalogued as COSV100721857, COSV100722293; called by muse, mutect2, varscan2
- TEX29 | c.304A>C p.S102R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.865); catalogued as COSV99366070; called by muse, mutect2, varscan2
- TEX29 | c.305G>C p.S102T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.327); catalogued as COSV99366074; called by muse, mutect2, varscan2
- TYSND1 | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99751932; called by muse, mutect2, varscan2
- XKR8 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs554587970, COSV100872036; called by muse, mutect2, varscan2
- ZNF667 | c.1766G>A p.G589E | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.208); catalogued as COSV99410569; called by muse, mutect2, varscan2
- NEB | c.4816G>A p.A1606T | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PCDHB12 | c.1391_1393del p.N464del | In Frame Del (DEL) | VAF 22/110 reads (20%) | called by pindel, varscan2
- PIK3R1 | c.1635_1639delinsT p.L545Ffs*4 (on ENST00000521381 / NM_181523.3; = p.L275Ffs*4 on NM_181504.4) | Frame Shift Del (DEL) | VAF 15/32 reads (47%) | called by pindel, varscan2*
- PTEN | c.232_233del p.T78Rfs*4 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | called by pindel, varscan2
- ADARB2 | c.474A>G p.V158= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV101186962; called by muse, mutect2, varscan2
- ADRA1B | c.177C>T p.A59= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV60703652; called by muse, mutect2, varscan2
- ADRA1B | c.465G>A p.T155= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100140267; called by muse, mutect2, varscan2
- ANGPT2 | c.1083G>C p.S361= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100290980, COSV57334681; called by muse, mutect2, varscan2
- ANKLE2 | c.2631G>A p.A877= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs563045182, COSV100785355; called by muse, mutect2, varscan2
- ASB9 | c.438C>T p.H146= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV66851563; called by muse, mutect2
- CDH23 | c.9948C>T p.T3316= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs556205551, COSV99821583; called by muse, mutect2, varscan2
- HOXA3 | c.885G>A p.P295= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV100415517; called by muse, mutect2, varscan2
- MAGED1 | c.642C>T p.T214= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs782743012, COSV100431638; called by muse, varscan2
- MAP1B | c.6552G>A p.S2184= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs771765179, COSV57098168, COSV99702470; called by muse, mutect2, varscan2
- MYG1 | c.798G>A p.A266= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs749844045, COSV99267010; called by muse, mutect2
- POTEH | c.150C>T p.D50= | Silent (SNP) | VAF 33/264 reads (13%) | catalogued as rs1233637713, COSV100625013, COSV58883227; called by muse, mutect2, varscan2
- PRKAR1B | c.381G>A p.A127= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs748586275, COSV64320287; called by muse, mutect2, varscan2
- PRKG2 | c.1602A>G p.L534= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100020002; called by muse, mutect2, varscan2
- RORC | c.594C>A p.A198= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV100561977; called by muse, mutect2
- SPTAN1 | c.6528G>A p.E2176= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV100823675; called by muse, mutect2, varscan2
- TBL3 | c.2274G>A p.E758= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs775825652, COSV100224940; called by muse, mutect2, varscan2
- ZNF224 | c.390C>T p.F130= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV61241478; called by muse, mutect2, varscan2
- ZNF536 | c.1963C>A p.R655= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as rs770369068, COSV62819659, COSV62832846; called by muse, mutect2, varscan2
- ZNF789 | c.1245C>T p.H415= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100507902; called by muse, mutect2, varscan2
- SNORD115-2 | n.5C>T | RNA (SNP) | VAF 14/58 reads (24%) | catalogued as rs199652866; called by muse, mutect2, varscan2
